Somatic mutation profile of tumor specimen HCM-CSHL-0064-C18-01A (aliquot HCM-CSHL-0064-C18-01A-01D-A768-36) from HCMI case HCM-CSHL-0064-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 75.4 years (27,552 days).
Specimen HCM-CSHL-0064-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15219cf9-5452-4576-8031-b989ee10f646.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0064-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0064-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a6a3954-981a-43f5-872e-e4b17adfeb25

The open-access MAF lists 321 somatic variants for this specimen: 203 protein-altering or splice-affecting, 74 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 74, Intron 20, Nonsense Mutation 20, 5'UTR 12, Frame Shift Del 5, RNA 5, Splice Site 4, 3'UTR 3, Splice Region 3, 5'Flank 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 136/423 reads (32%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.591); catalogued as COSV61820758; called by muse, mutect2, varscan2
- AGBL1 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as rs773153038, COSV66858794; called by muse, mutect2
- ALK | c.1562T>A p.L521H | Missense Mutation (SNP) | VAF 49/484 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV66568222; called by muse, mutect2, varscan2
- ANKRD24 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs866437534; called by muse, mutect2, varscan2
- APEH | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs758904075; called by muse, mutect2, varscan2
- ASPG | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1170649369; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs569799893; called by muse, mutect2, varscan2
- C2CD2L | c.125C>G p.A42G | Missense Mutation (SNP) | VAF 45/403 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1040454427; called by muse, mutect2, varscan2
- CCER1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs868224869; called by muse, mutect2, varscan2
- CCKBR | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as rs1181500642, COSV100582881; called by muse, mutect2, varscan2
- CEP295 | c.6727G>C p.D2243H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV57344855; called by muse, mutect2, varscan2
- CHMP4B | c.327G>A p.M109I | Missense Mutation (SNP) | VAF 48/606 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99459768; called by muse, mutect2
- CLCN1 | c.2449G>T p.D817Y | Missense Mutation (SNP) | VAF 224/587 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs763760683; called by muse, mutect2, varscan2
- CNGB1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 64/752 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs764107600, COSV51905464; called by muse, mutect2
- COL12A1 | c.7869C>A p.N2623K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201337277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRMP1 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs370759908; called by muse, mutect2, varscan2
- DNAJA1 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV99044021; called by muse, mutect2, varscan2
- DNAJC13 | c.6344G>A p.R2115Q | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as rs770715465, CM141864, COSV53450154; called by muse, mutect2, varscan2
- DTNB | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777533811; called by muse, mutect2
- ECPAS | c.3916C>T p.L1306F | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52191015; called by muse, varscan2
- ELAVL2 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 34/514 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.093); catalogued as rs1188175446, COSV99805698; called by muse, mutect2
- EPN3 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746697052, COSV52141953; called by muse, mutect2, varscan2
- FAM83B | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 103/421 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1465244268; called by muse, mutect2, varscan2
- FCRL5 | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV99052721; called by muse, mutect2
- FOXO1 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769622051; called by muse, mutect2, varscan2
- GALNT17 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV61149754; called by muse, mutect2, varscan2
- GJD4 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs778114104, COSV58702441; called by muse, mutect2, varscan2
- GOLGA4 | c.6347C>T p.T2116M | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs780800757; called by muse, mutect2, varscan2
- GRM6 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51451186; called by muse, mutect2, varscan2
- HLA-F | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 84/279 reads (30%) | catalogued as rs747319246; called by muse, mutect2, varscan2
- IKZF1 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.148); catalogued as COSV100497807, COSV58784077; called by muse, mutect2
- KAT2B | c.306C>T p.A102= | Splice Region (SNP) | VAF 16/145 reads (11%) | catalogued as rs894033666, COSV55431080; called by muse, mutect2, varscan2
- KCNT2 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99652280; called by muse, mutect2, varscan2
- KLC2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as rs765203566, COSV100270558; called by muse, mutect2, varscan2
- KLK6 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 65/185 reads (35%) | catalogued as rs377282019, COSV100037783; called by muse, mutect2, varscan2
- KMT2B | c.4847C>T p.A1616V | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55866983, COSV99720244; called by muse, mutect2, varscan2
- LTN1 | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs1466784065; called by muse, mutect2
- MCC | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs764285047; called by muse, mutect2, varscan2
- MROH5 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 30/294 reads (10%) | catalogued as rs549578686, COSV101436180; called by muse, varscan2
- MROH9 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.073); catalogued as rs748891805, COSV63010002; called by muse, mutect2, varscan2
- MS4A18 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs534337923, COSV67517736; called by muse, mutect2, varscan2
- NPIPB15 | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 94/2072 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.78); catalogued as rs761593756, COSV70437899; called by muse, mutect2
- OFD1 | c.412+8C>G | Splice Region (SNP) | VAF 35/157 reads (22%) | catalogued as COSV60794453; called by muse, mutect2, varscan2
- OR4D9 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs535085659, COSV61434513; called by muse, mutect2, varscan2
- OR5D18 | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1376035809; called by muse, mutect2
- OTOF | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 67/466 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1245016113, COSV55498199, COSV55502880; called by muse, mutect2, varscan2
- PCDHB7 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 125/1116 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.458); catalogued as rs148889209; called by muse, mutect2, varscan2
- PCDHB9 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 99/566 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); catalogued as rs782349216; called by muse, mutect2, varscan2
- PDE1C | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775393302, COSV58502926; called by muse, mutect2, varscan2
- PDILT | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs765889720; called by muse, mutect2, varscan2
- PKHD1 | c.9120C>A p.D3040E | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV61890691; called by muse, mutect2, varscan2
- POM121L12 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 22/292 reads (8%) | catalogued as COSV68694686; called by muse, mutect2
- PPP1R13L | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs759404256; called by muse, mutect2, varscan2
- PRAME | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs201064885; called by muse, mutect2, varscan2
- PROCR | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 103/883 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs774060495; called by muse, mutect2, varscan2
- PRSS56 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1263692375; called by muse, mutect2
- QRICH2 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772000651, COSV53154869, COSV53158477; called by muse, mutect2, varscan2
- RAB3D | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs200374153; called by muse, mutect2, varscan2
- RAP1GDS1 | c.544A>T p.I182F (on ENST00000408927 / NM_001100427.2; = p.I183F on NM_021159.5) | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV52786764; called by muse, mutect2, varscan2
- RBM20 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs923358109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs370474035; called by muse, mutect2, varscan2
- SLC4A3 | c.538G>T p.G180W | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV99813087; called by muse, varscan2
- SLC5A11 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 58/638 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1567658010, COSV61744060; called by muse, mutect2
- SLC6A5 | c.388G>T p.G130W | Missense Mutation (SNP) | VAF 49/503 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV54225086; called by muse, mutect2
- SLITRK1 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 29/334 reads (9%) | catalogued as rs1041104860, COSV65674040, COSV65675357; called by muse, mutect2
- SYTL3 | c.1034C>T p.P345L (on ENST00000611299 / NM_001242394.1; = p.P277L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774253415, COSV51908430, COSV99791835; called by muse, mutect2, varscan2
- TBC1D9 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778160381; called by muse, mutect2, varscan2
- TELO2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1281622827; called by muse, mutect2, varscan2
- TM9SF2 | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225294102; called by muse, mutect2
- TMEM132A | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.809); catalogued as rs753135679, COSV50013072; called by muse, mutect2, varscan2
- TSPYL4 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV60305651; called by muse, mutect2, varscan2
- TXNDC12 | c.44T>A p.F15Y | Missense Mutation (SNP) | VAF 66/310 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.047); catalogued as rs766482803; called by muse, mutect2, varscan2
- UBA7 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757115951; called by muse, mutect2, varscan2
- UGT2B7 | c.1190C>G p.A397G | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV59442867; called by muse, mutect2, varscan2
- UNC80 | c.422G>T p.W141L | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.106); catalogued as COSV55904593; called by muse, mutect2
- VWCE | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs541004294, COSV57113297; called by muse, mutect2
- VXN | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757732888, COSV59685450; called by muse, mutect2, varscan2
- WRNIP1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.179); catalogued as rs750497757; called by muse, mutect2
- ZC3H4 | c.3868G>A p.V1290I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1288669302; called by muse, mutect2, varscan2
- ZFHX2 | c.7028G>A p.G2343D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV70220418; called by muse, mutect2, varscan2
- ZFP64 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 140/1092 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749217635; called by muse, mutect2, varscan2
- ZNF311 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs1156904558; called by muse, mutect2, varscan2
- ABCA2 | c.4778A>T p.E1593V (on ENST00000614293; = p.E1563V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- AC100868.1 | c.1250C>T p.T417I | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2
- ACACA | c.5451C>G p.Y1817* | Nonsense Mutation (SNP) | VAF 48/247 reads (19%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.2635G>T p.A879S | Missense Mutation (SNP) | VAF 50/738 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.145); called by muse, mutect2
- ARHGAP15 | c.369G>T p.Q123H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, varscan2
- ARHGAP32 | c.5508G>A p.M1836I (on ENST00000310343 / NM_001378025.1; = p.M1487I on NM_014715.4) | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ARID5A | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ARMC1 | c.406G>C p.G136R | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- ARNTL2 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ATP11B | c.2642_2643insG p.Y881* | Nonsense Mutation (INS) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- C20orf96 | c.307A>T p.T103S (on ENST00000360321 / NM_153269.3; = p.T102S on NM_080571.1) | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C3orf84 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.047); called by muse, mutect2
- CC2D2B | c.131A>T p.K44M (on ENST00000646931 / NM_001349008.3; = p.K36M on NM_001130446.3) | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CCDC168 | c.13066G>C p.D4356H | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2
- CCDC91 | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC91 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- CCL23 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- CDC14A | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 19/199 reads (10%) | called by muse, mutect2
- CEP128 | c.1383C>A p.Y461* | Nonsense Mutation (SNP) | VAF 91/396 reads (23%) | called by muse, mutect2, varscan2
- CMYA5 | c.5572A>T p.R1858* | Nonsense Mutation (SNP) | VAF 25/253 reads (10%) | called by muse, mutect2, varscan2
- COL25A1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL4A5 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- COL6A3 | c.6625A>T p.K2209* | Nonsense Mutation (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- COX19 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CPO | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.266); called by muse, mutect2
- CTH | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 61/574 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.7517A>G p.N2506S | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- DNAH9 | c.4407A>G p.I1469M | Missense Mutation (SNP) | VAF 44/257 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- DNAJB7 | c.881_882insC p.K294Nfs*5 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- DOCK2 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- DOCK8 | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 63/544 reads (12%) | called by muse, mutect2, varscan2
- DPY19L3 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DSCC1 | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DUSP1 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDC3 | c.1192+6C>G | Splice Region (SNP) | VAF 38/353 reads (11%) | called by muse, mutect2, varscan2
- ELMO2 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.024); called by muse, mutect2
- ENAM | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ERBIN | c.2650T>G p.Y884D | Missense Mutation (SNP) | VAF 37/351 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FAM20B | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.38); called by muse, mutect2
- FAM234B | c.1741A>T p.S581C | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FKBP6 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 44/748 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- FNBP4 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FRAS1 | c.8927_8928del p.S2976Ffs*21 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | called by pindel, varscan2
- FRMD3 | c.614T>C p.V205A | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- FRYL | c.989T>G p.L330* | Nonsense Mutation (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- GP6 | c.998A>C p.H333P | Missense Mutation (SNP) | VAF 81/632 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR150 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSG1L | c.890A>T p.Y297F (on ENST00000447459 / NM_001109763.2; = p.Y142F on NM_144675.2) | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- HIP1 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXD10 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 48/426 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, varscan2
- IDO1 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JAK2 | c.2816A>G p.D939G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.975); called by muse, mutect2
- KCNT2 | c.175+2T>A p.X59_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- KIF11 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- KIF13A | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KIF2B | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LAMB3 | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 41/384 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LAT2 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCA5 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 47/484 reads (10%) | called by muse, mutect2
- LCP2 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- LILRB1 | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.038); called by muse, mutect2
- LIPI | c.657A>T p.L219F | Missense Mutation (SNP) | VAF 59/567 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCOLN1 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MLF2 | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2
- MMP12 | c.108C>G p.Y36* | Nonsense Mutation (SNP) | VAF 17/198 reads (9%) | called by muse, mutect2
- MRPL3 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH10 | c.3858+1G>A p.X1286_splice | Splice Site (SNP) | VAF 21/113 reads (19%) | called by muse, mutect2
- NARS1 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFKBIL1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 66/714 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NPIPB15 | c.767T>G p.I256R | Missense Mutation (SNP) | VAF 92/2065 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.893); called by muse, mutect2
- OR2T27 | c.393C>G p.H131Q | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- OR7A17 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OTX1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAK1IP1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH11X | c.3577A>G p.I1193V | Missense Mutation (SNP) | VAF 463/771 reads (60%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDPR | c.2563C>G p.L855V | Missense Mutation (SNP) | VAF 50/588 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PLA2G7 | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 126/666 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLG | c.2296T>A p.C766S | Missense Mutation (SNP) | VAF 23/623 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- PRRT3 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PSG4 | c.763A>G p.K255E | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.05); called by muse, mutect2
- PTK2 | c.789+2T>A p.X263_splice | Splice Site (SNP) | VAF 38/480 reads (8%) | called by muse, mutect2
- RANBP3 | c.776C>G p.A259G (on ENST00000340578 / NM_007322.3; = p.A254G on NM_003624.3) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RANBP6 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RBFOX2 | c.510A>C p.Q170H (on ENST00000438146 / NM_001349995.2; = p.Q100H on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RPN2 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 79/1224 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- RRAD | c.191_203del p.G64Afs*65 | Frame Shift Del (DEL) | VAF 29/171 reads (17%) | called by mutect2, pindel
- SAMD9L | c.2916A>G p.I972M | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2
- SH3D19 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2
- SLC24A5 | c.584T>A p.V195D | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLIT2 | c.458T>A p.I153K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- SPAG16 | c.1262G>A p.W421* | Nonsense Mutation (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- SPEF2 | c.3598G>C p.D1200H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SRM | c.221_224del p.R74Tfs*8 | Frame Shift Del (DEL) | VAF 27/179 reads (15%) | called by mutect2, pindel, varscan2
- STK17A | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STS | c.892A>T p.S298C | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TAAR2 | c.337C>T p.L113F (on ENST00000367931 / NM_001033080.1; = p.L68F on NM_014626.3) | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- TBC1D19 | c.1507-1G>A p.X503_splice | Splice Site (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- TESK2 | c.1492_1494del p.P498del | In Frame Del (DEL) | VAF 36/344 reads (10%) | called by pindel, varscan2
- THADA | c.1821T>A p.H607Q | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TMTC1 | c.1249A>T p.S417C (on ENST00000539277 / NM_001193451.2; = p.S309C on NM_175861.3) | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRERF1 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TTN | c.14291T>G p.L4764R (on ENST00000591111; = p.L3837R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUBGCP2 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBR5 | c.1502A>G p.Q501R | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2
- USP25 | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2
- USP9X | c.5366T>A p.L1789* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2
- VEGFC | c.1040G>T p.C347F | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- VPS13A | c.6548T>C p.F2183S | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- VPS13D | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- VWA5B2 | c.3149G>C p.S1050T | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VWA8 | c.923T>A p.L308H | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- WDR24 | c.372G>C p.K124N (on ENST00000248142; = p.K62N on NM_032259.4) | Missense Mutation (SNP) | VAF 44/517 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.214); called by muse, mutect2
- XCL1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2
- ZDBF2 | c.1437T>G p.H479Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF268 | c.2362del p.A788Lfs*8 | Frame Shift Del (DEL) | VAF 28/280 reads (10%) | called by mutect2, varscan2
- ZNF320 | c.1435_1436insAG p.S479Kfs*3 | Frame Shift Ins (INS) | VAF 28/245 reads (11%) | called by mutect2, varscan2*
- ZNF320 | c.1433_1434del p.F478* | Frame Shift Del (DEL) | VAF 28/256 reads (11%) | called by mutect2, varscan2*
- ZNF512B | c.1751T>C p.L584P | Missense Mutation (SNP) | VAF 169/486 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNHIT6 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZSWIM1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 48/760 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- ABCA13 | c.7425T>G p.T2475= | Silent (SNP) | VAF 21/207 reads (10%) | called by muse, mutect2
- AC008397.2 | c.1455A>C p.R485= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- ACTRT2 | c.540C>A p.T180= | Silent (SNP) | VAF 33/256 reads (13%) | catalogued as COSV65759067; called by muse, mutect2, varscan2
- ADAMTS5 | c.136C>A p.R46= | Silent (SNP) | VAF 31/276 reads (11%) | called by muse, mutect2, varscan2
- ANKRD66 | c.258T>G p.G86= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- AP2M1 | c.591G>A p.S197= | Silent (SNP) | VAF 30/424 reads (7%) | catalogued as rs771453400, COSV53047759, COSV53048423; called by muse, mutect2
- BACH2 | c.1572T>G p.S524= | Silent (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- BTBD11 | c.1266A>C p.V422= | Silent (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- CDH22 | c.2091C>G p.L697= | Silent (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- CEP290 | c.4776T>A p.A1592= | Silent (SNP) | VAF 31/202 reads (15%) | called by muse, mutect2, varscan2
- CFAP69 | c.678T>A p.T226= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- CHODL | c.51C>T p.H17= | Silent (SNP) | VAF 15/450 reads (3%) | called by muse, mutect2
- COL11A2 | c.243C>T p.P81= | Silent (SNP) | VAF 185/842 reads (22%) | called by muse, mutect2, varscan2
- COL22A1 | c.1632C>T p.D544= | Silent (SNP) | VAF 32/373 reads (9%) | catalogued as rs373172764; called by muse, mutect2
- COL24A1 | c.3729A>G p.G1243= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- COL28A1 | c.960C>T p.P320= | Silent (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- COL5A2 | c.2205A>C p.G735= | Silent (SNP) | VAF 44/468 reads (9%) | called by muse, mutect2
- CYP1B1 | c.249C>T p.D83= | Silent (SNP) | VAF 75/287 reads (26%) | catalogued as COSV99572680; called by muse, mutect2, varscan2
- DACT3 | c.954C>T p.A318= | Silent (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- DMD | c.9594T>C p.S3198= | Silent (SNP) | VAF 109/231 reads (47%) | called by muse, mutect2, varscan2
- DNAH1 | c.8550G>A p.Q2850= | Silent (SNP) | VAF 75/338 reads (22%) | called by muse, mutect2, varscan2
- DNAH14 | c.885T>G p.P295= (on ENST00000445597; = p.P168= on NM_144989.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2
- EGR4 | c.1653G>A p.A551= (on ENST00000545030; = p.A448= on NM_001965.4) | Silent (SNP) | VAF 36/418 reads (9%) | catalogued as COSV71532047; called by muse, mutect2
- EMILIN2 | c.1389C>T p.N463= | Silent (SNP) | VAF 74/194 reads (38%) | catalogued as rs1363674860; called by muse, mutect2, varscan2
- ESR1 | c.738C>T p.Y246= | Silent (SNP) | VAF 67/364 reads (18%) | catalogued as rs970273955, COSV52782193, COSV99241207; called by muse, mutect2, varscan2
- FOXC2 | c.1149C>T p.A383= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as rs1379344558; called by muse, mutect2, varscan2
- GPR61 | c.681C>T p.V227= | Silent (SNP) | VAF 51/237 reads (22%) | called by muse, mutect2, varscan2
- HCN1 | c.939T>C p.G313= | Silent (SNP) | VAF 17/265 reads (6%) | catalogued as rs746190871, COSV100299101; called by muse, mutect2
- HTR3E | c.936C>T p.F312= (on ENST00000415389 / NM_001256613.1; = p.F327= on NM_182589.2) | Silent (SNP) | VAF 188/435 reads (43%) | catalogued as rs200034444; called by muse, mutect2, varscan2
- IGFBP1 | c.168C>T p.G56= | Silent (SNP) | VAF 182/645 reads (28%) | called by muse, mutect2, varscan2
- IPO8 | c.267C>G p.R89= | Silent (SNP) | VAF 28/261 reads (11%) | called by muse, mutect2
- ITGB7 | c.372G>C p.A124= | Silent (SNP) | VAF 21/170 reads (12%) | called by muse, varscan2
- ITPRIPL2 | c.378C>A p.I126= | Silent (SNP) | VAF 45/216 reads (21%) | called by muse, mutect2, varscan2
- KANSL1L | c.1686A>T p.T562= | Silent (SNP) | VAF 41/405 reads (10%) | called by muse, mutect2, varscan2
- KCNJ2 | c.1050C>T p.V350= | Silent (SNP) | VAF 16/476 reads (3%) | called by muse, mutect2
- KDM3B | c.177G>A p.V59= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs770495938; called by muse, mutect2, varscan2
- KIF26B | c.2604C>T p.I868= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as rs375496913; called by muse, mutect2, varscan2
- LRP1B | c.13542T>C p.F4514= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as rs754357317; called by muse, mutect2, varscan2
- LRP3 | c.1446C>T p.D482= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs200274257; called by muse, mutect2
- LSM11 | c.897G>C p.G299= | Silent (SNP) | VAF 45/324 reads (14%) | catalogued as COSV99643901; called by muse, mutect2, varscan2
- MAML1 | c.2817G>A p.G939= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as rs775764590; called by muse, mutect2, varscan2
- MAPK7 | c.489G>C p.L163= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, mutect2, varscan2
- MIA2 | c.786T>C p.S262= | Silent (SNP) | VAF 53/225 reads (24%) | called by muse, mutect2, varscan2
- MYLK3 | c.927C>T p.G309= | Silent (SNP) | VAF 26/221 reads (12%) | catalogued as rs752211624; called by muse, mutect2, varscan2
- NCK1 | c.333T>C p.A111= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- NLRP8 | c.1077G>A p.T359= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs1000244011, COSV52587062; called by muse, mutect2, varscan2
- NPBWR1 | c.153T>G p.G51= | Silent (SNP) | VAF 42/407 reads (10%) | called by muse, mutect2, varscan2
- PAXBP1 | c.135T>A p.G45= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV51608328; called by muse, mutect2
- PEG10 | c.966G>A p.P322= (on ENST00000482108 / NM_001040152.2; = p.G356S on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as COSV101509847; called by muse, mutect2, varscan2
- PPDPF | c.201C>T p.F67= | Silent (SNP) | VAF 62/715 reads (9%) | called by muse, mutect2
- RELN | c.3462C>A p.L1154= | Silent (SNP) | VAF 205/628 reads (33%) | catalogued as COSV58996490, COSV59040219; called by muse, mutect2, varscan2
- RNF213 | c.5181G>A p.T1727= | Silent (SNP) | VAF 36/330 reads (11%) | catalogued as rs1043643434, COSV60411763; called by muse, mutect2, varscan2
- RPS6KA2 | c.1317C>T p.T439= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as rs1336557047, COSV55821006; called by muse, mutect2, varscan2
- SHOC2 | c.507G>A p.K169= | Silent (SNP) | VAF 50/390 reads (13%) | called by muse, varscan2
- SLC1A2 | c.78G>A p.E26= | Silent (SNP) | VAF 46/215 reads (21%) | called by muse, mutect2, varscan2
- SLFN14 | c.2067T>C p.T689= | Silent (SNP) | VAF 67/495 reads (14%) | called by muse, mutect2, varscan2
- SLITRK6 | c.2475T>C p.A825= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2
- SMO | c.1416C>T p.Y472= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs766775464, COSV50842459; called by muse, mutect2
- SOX17 | c.738G>A p.P246= | Silent (SNP) | VAF 43/280 reads (15%) | catalogued as rs753314063; called by muse, mutect2, varscan2
- STOX2 | c.1284C>T p.N428= | Silent (SNP) | VAF 35/235 reads (15%) | catalogued as rs183419852; called by muse, mutect2, varscan2
- STRN | c.579C>T p.V193= | Silent (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- TMEM168 | c.987A>G p.V329= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs749060676; called by muse, mutect2, varscan2
- TRIM71 | c.40C>T p.L14= | Silent (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- TTN | c.7551G>A p.L2517= (on ENST00000591111; = p.L2471= on NM_003319.4) | Silent (SNP) | VAF 28/231 reads (12%) | called by muse, mutect2, varscan2
- U2SURP | c.898T>C p.L300= | Silent (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- USH2A | c.4389A>G p.L1463= | Silent (SNP) | VAF 52/428 reads (12%) | called by muse, varscan2
- VPS13A | c.2673G>A p.L891= | Silent (SNP) | VAF 51/437 reads (12%) | called by muse, mutect2, varscan2
- XDH | c.3624C>A p.T1208= | Silent (SNP) | VAF 33/309 reads (11%) | called by muse, mutect2, varscan2
- XKR4 | c.1440T>G p.A480= | Silent (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- YEATS2 | c.2817G>A p.S939= | Silent (SNP) | VAF 46/294 reads (16%) | catalogued as rs777936756; called by muse, mutect2, varscan2
- ZBTB8B | c.1317C>A p.P439= | Silent (SNP) | VAF 78/625 reads (12%) | called by muse, mutect2, varscan2
- ZDBF2 | c.597A>T p.P199= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- ZNF469 | c.10749G>C p.A3583= (on ENST00000437464; = p.A3611= on NM_001367624.2) | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- ZNF677 | c.336T>C p.Y112= | Silent (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- AFG3L2 | c.-4G>A | 5'UTR (SNP) | VAF 91/244 reads (37%) | called by muse, mutect2, varscan2
- AL163540.1 | n.359G>T | RNA (SNP) | VAF 18/408 reads (4%) | called by muse, mutect2
- AL353753.1 | n.471A>C | RNA (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- AMT | c.696+32G>T | Intron (SNP) | VAF 49/483 reads (10%) | called by muse, mutect2
- ANKRD26P1 | n.708C>A | RNA (SNP) | VAF 13/139 reads (9%) | called by muse, mutect2, varscan2
- APLF | c.*123C>A | 3'UTR (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- AVPR2 | chrX:153902712 C>T | 5'Flank (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- BAHCC1 | c.-119C>A | 5'UTR (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
- BRCA2 | c.-8A>T | 5'UTR (SNP) | VAF 27/388 reads (7%) | called by muse, mutect2
- C2CD6 | c.1581+3244T>G | Intron (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99635227; called by muse, mutect2, varscan2
- CELF4 | c.658-84C>T | Intron (SNP) | VAF 91/217 reads (42%) | catalogued as COSV100612084; called by muse, mutect2, varscan2
- COL4A1 | c.-18C>T | 5'UTR (SNP) | VAF 40/485 reads (8%) | catalogued as rs1222089552; called by muse, mutect2
- CORO6 | c.-173G>C | 5'UTR (SNP) | VAF 56/209 reads (27%) | called by muse, mutect2, varscan2
- DSCAML1 | c.*42G>A | 3'UTR (SNP) | VAF 22/202 reads (11%) | catalogued as rs762695017; called by muse, mutect2
- EFCAB14 | c.1074+32A>T | Intron (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- ERICH1 | c.-5C>A | 5'UTR (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- GATM | chr15:45378564 G>A | 5'Flank (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- HP | c.5+60A>G | Intron (SNP) | VAF 39/580 reads (7%) | catalogued as rs1452531144, COSV63325746; called by muse, mutect2
- HSPA7 | n.395C>T | RNA (SNP) | VAF 74/316 reads (23%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23942A>T | Intron (SNP) | VAF 31/401 reads (8%) | called by muse, mutect2
- KIAA1958 | c.1172-27194G>C | Intron (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- LRP2 | c.13200-41A>T | Intron (SNP) | VAF 54/368 reads (15%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+3658C>T | Intron (SNP) | VAF 49/258 reads (19%) | catalogued as rs1480392453; called by muse, mutect2, varscan2
- MED13L | c.6501-23G>T | Intron (SNP) | VAF 47/395 reads (12%) | called by muse, mutect2, varscan2
- MFN2 | c.817-22G>A | Intron (SNP) | VAF 56/395 reads (14%) | called by muse, mutect2, varscan2
- MUS81 | c.-49C>T | 5'UTR (SNP) | VAF 54/370 reads (15%) | called by muse, mutect2, varscan2
- NDRG4 | c.37+11176C>A | Intron (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- NSMF | c.-5C>A | 5'UTR (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- PHACTR2 | c.14-33921G>C | Intron (SNP) | VAF 32/263 reads (12%) | catalogued as COSV99991280; called by muse, mutect2, varscan2
- PPIA | c.-22G>T | 5'UTR (SNP) | VAF 35/396 reads (9%) | called by muse, mutect2
- RFT1 | c.1102+47_1102+49del | Intron (DEL) | VAF 40/313 reads (13%) | called by mutect2, pindel, varscan2
- RN7SL495P | chr15:22611773 T>A | 5'Flank (SNP) | VAF 31/400 reads (8%) | called by muse, mutect2, varscan2
- RPS3 | chr11:75405638 G>A | 3'Flank (SNP) | VAF 38/326 reads (12%) | called by muse, mutect2, varscan2
- S100A11 | c.-22C>G | 5'UTR (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- SBF1 | c.-141C>T | 5'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as rs1460204952; called by muse, mutect2, varscan2
- SCARF2 | c.*43C>T | 3'UTR (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- SERPINB11 | c.618+37G>T | Intron (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.191C>T | RNA (SNP) | VAF 40/333 reads (12%) | catalogued as rs1175038660; called by muse, mutect2, varscan2
- SSB | c.345+176C>T | Intron (SNP) | VAF 22/83 reads (27%) | catalogued as rs1167392178; called by muse, mutect2, varscan2
- STRA8 | c.420-9T>G | Intron (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- STX3 | c.-88C>T | 5'UTR (SNP) | VAF 27/231 reads (12%) | called by muse, mutect2, varscan2
- TTYH1 | c.126+1147G>A | Intron (SNP) | VAF 144/396 reads (36%) | called by muse, mutect2, varscan2
- TXNDC9 | c.309-461C>A | Intron (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- UMODL1 | c.1900-58G>A | Intron (SNP) | VAF 73/319 reads (23%) | called by muse, mutect2, varscan2
